TARGET case TARGET-15-SJMPAL012424 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17667e8b-8f00-4444-9e8d-26962349beda

Demographics
Sex at birth: male; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 8.4 years (3,050 days); Year of diagnosis: 2011; Days to last follow up: 1,855 days (5.1 years).

Follow-up (1 entry)
- Days to follow up: 1,855 days (5.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,855; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 288 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL012424-03A.1, TARGET-15-SJMPAL012424-03A.2 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL012424-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012425-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1855
- Protocol: St. Jude
- WBC at Diagnosis: 288.4
- Initial Therapy: ALL
- Karyotype: 46,XY,der(9)t(9;11;14)(14qter->14q32.3::11q23->11q23::14q32.3->14q22::9p22->9qter),der(11)t(9;11)(p22;q23),der(14)t(11;14)(q24;q22)[12]/46,idem,i(8)(q10)[8]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
